Somatic mutation profile of tumor specimen C3L-02984-01 (aliquot CPT0190240007) from CPTAC case C3L-02984, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 34.1 years (12,449 days).
Specimen C3L-02984-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Lobe; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0d1523bd-0749-4a5e-ab96-c5fe5431a8ff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02984-31 (Blood Derived Normal), aliquot CPT0191140002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/efb54683-2d2c-44c2-9bc7-911588d5cc64

The open-access MAF lists 10 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 2, Intron 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 62/155 reads (40%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by mutect2, varscan2
- TP53 | c.713G>T p.C238F | Missense Mutation (SNP) | VAF 339/407 reads (83%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730882005, CM034930, COSV52661646, COSV52706816, COSV52804264; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ATRX | c.4540C>T p.R1514* | Nonsense Mutation (SNP) | VAF 83/95 reads (87%) | catalogued as COSV64871896; called by muse, mutect2, varscan2
- COLGALT1 | c.1207C>T p.R403W | Missense Mutation (SNP) | VAF 76/211 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1360393885; called by muse, mutect2, varscan2
- ATM | c.3769C>T p.P1257S | Missense Mutation (SNP) | VAF 6/99 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.857); called by muse, mutect2
- SRSF1 | c.135C>G p.I45M | Missense Mutation (SNP) | VAF 9/247 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2
- ZSCAN5B | c.638del p.N213Tfs*13 | Frame Shift Del (DEL) | VAF 85/233 reads (36%) | called by mutect2, pindel, varscan2
- CCKBR | c.541C>T p.L181= | Silent (SNP) | VAF 24/500 reads (5%) | catalogued as rs199530800; called by muse, mutect2
- FAM83D | c.1185A>C p.P395= | Silent (SNP) | VAF 20/306 reads (7%) | catalogued as COSV54157938; called by muse, mutect2
- OBSCN | c.18662-2926C>T | Intron (SNP) | VAF 34/80 reads (43%) | called by muse, mutect2, varscan2
